Somatic mutation profile of tumor specimen TCGA-VR-AA4G-01A (aliquot TCGA-VR-AA4G-01A-11D-A37C-09) from TCGA case TCGA-VR-AA4G, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,909 days).
Specimen TCGA-VR-AA4G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92b39fb6-8ee8-403f-87c1-3eacc5be5d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-AA4G-10A (Blood Derived Normal), aliquot TCGA-VR-AA4G-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adeab8ab-79e7-4bcb-a3a8-45c518916509

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 43, Silent 19, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV59936823; called by muse, mutect2, varscan2
- ALMS1 | c.8993A>C p.N2998T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs895984182; called by muse, mutect2, varscan2
- CDC20 | c.556+2dup p.X186_splice | Splice Site (INS) | VAF 7/32 reads (22%) | catalogued as rs755204301; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4388A>G p.N1463S | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs748523387; called by muse, mutect2, varscan2
- CHRND | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs146416320, COSV51317337, COSV99285993; called by muse, mutect2, varscan2
- CLVS2 | c.686A>C p.H229P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99033990; called by muse, mutect2, varscan2
- COL11A2 | c.1451C>T p.A484V (on ENST00000341947 / NM_080680.3; = p.A377V on NM_080679.2) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143965711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.4183C>G p.L1395V (on ENST00000361203 / NM_001374722.1; = p.L1069V on NM_001723.6) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388548098, COSV55046927; called by muse, mutect2, varscan2
- FXR1 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs1200819381; called by muse, mutect2, varscan2
- GCN1 | c.4835C>T p.S1612F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56115549; called by muse, mutect2, varscan2
- HP | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367968695; called by muse, mutect2, varscan2
- KLF17 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs745641456, COSV64856278; called by muse, mutect2, varscan2
- PCDH11X | c.3950C>T p.S1317L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs1201676026, COSV53462412, COSV53480138; called by muse, mutect2, varscan2
- PPP1R2 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60498583; called by muse, mutect2, varscan2
- RASAL2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs757727946; called by muse, mutect2, varscan2
- RP1 | c.6182T>C p.I2061T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs539588544; called by muse, mutect2, varscan2
- SLC9A4 | c.510del p.L171Wfs*13 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV54836047; called by mutect2, pindel, varscan2
- TGFBR2 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV99847567; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TP53 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV52677652, COSV52734727, COSV52787469, COSV53371041; called by muse, mutect2, varscan2
- VPS16 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs762665854; called by muse, mutect2, varscan2
- ADGRA2 | c.962G>T p.W321L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- ALG10 | c.26dup p.S10Lfs*41 | Frame Shift Ins (INS) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- BTAF1 | c.1239A>G p.I413M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COL6A3 | c.6761G>A p.G2254E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DDB1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DMXL2 | c.6176C>A p.A2059D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EVC | c.2275A>T p.S759C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- FAM220A | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IAH1 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IKZF3 | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- IL4R | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JMJD8 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNA7 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NOD1 | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.17325G>T p.Q5775H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, varscan2
- PCLO | c.6917A>G p.K2306R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PLEKHA3 | c.313+2T>C p.X105_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- ROCK1 | c.3055A>G p.R1019G | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL37A | c.73A>T p.M25L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SDHD | c.469T>C p.W157R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L2 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SERTAD3 | c.542G>C p.W181S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SUPT6H | c.3671A>T p.Q1224L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- TOPORS | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TPMT | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- TSPYL2 | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZCCHC2 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, varscan2
- ZNF107 | c.1866C>A p.N622K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- AC024598.1 | c.942C>T p.G314= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1156349778; called by muse, mutect2, varscan2
- ASB17 | c.255T>C p.F85= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1303098446; called by muse, varscan2
- CFAP46 | c.426G>A p.P142= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs148231376; called by muse, mutect2, varscan2
- CFAP61 | c.2706C>A p.I902= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CHODL | c.696G>A p.L232= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54732767; called by muse, mutect2, varscan2
- CWC22 | c.495A>T p.S165= | Silent (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
- EPB41L2 | c.2769G>C p.L923= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- EPHA6 | c.2772T>G p.A924= (on ENST00000389672 / NM_001080448.3; = p.A316= on NM_173655.4) | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- IDH3G | c.852C>T p.C284= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1174952903, COSV99473518; called by muse, mutect2, varscan2
- ITGA5 | c.2208C>T p.P736= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- MUC20 | c.1983T>G p.G661= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- OR5AP2 | c.189C>G p.T63= | Silent (SNP) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- PMEPA1 | c.60C>T p.V20= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, varscan2
- RBM17 | c.12C>T p.Y4= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs369487973; called by muse, mutect2, varscan2
- SHCBP1 | c.438A>G p.E146= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- SUMF1 | c.789C>A p.G263= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- TCP11 | c.1155T>C p.S385= (on ENST00000512012; = p.S323= on NM_018679.5) | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV55133447; called by muse, mutect2, varscan2
- TMC5 | c.483G>A p.P161= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs771364798, COSV101196912, COSV66869354; called by muse, mutect2, varscan2
- TRIM42 | c.222C>T p.P74= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs757444882; called by muse, mutect2, varscan2
